CCDI case PBCNFU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/22229cf7-d67b-41c1-8cc3-80f1e5f0e192

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 10.4 years (3,781 days).

Biospecimens (3 samples)
- Sample 0DWGJ0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DWGJV, 0DWGK1 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
